TCGA case TCGA-E1-A7YV — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/23c335f6-5749-4443-8ae8-61cccbb137cb

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 26 years; Vital status: Dead; Days to death: 987 days (2.7 years).

Diagnoses (7)
1. Mixed glioma (the primary disease): ICD-O-3 morphology code: 9382/3; ICD-10 code: C71.0; Tissue or organ of origin: Cerebrum; Site of resection or biopsy: Nervous system, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 26.1 years (9,546 days); Year of diagnosis: 2010; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 987 days (2.7 years); First symptom longest duration: 0-30 Days; First symptom prior to diagnosis: Headaches; Sites of involvement: Brain, Frontal lobe.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 38 days; Days to treatment end: 82 days; Treatment dose: 5,940 cGy; Treatment outcome: Progressive Disease; Number of fractions: 33; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Days to treatment start: 38 days; Days to treatment end: 82 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Days to treatment start: 70 days; Days to treatment end: 156 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Bevacizumab; Days to treatment start: 195 days; Days to treatment end: 507 days (1.4 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Bevacizumab; Days to treatment start: 507 days (1.4 years); Days to treatment end: 674 days (1.8 years); Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Imatinib Mesylate; Days to treatment start: 507 days (1.4 years); Days to treatment end: 674 days (1.8 years); Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Imatinib Mesylate; Days to treatment start: 678 days (1.9 years); Days to treatment end: 824 days (2.3 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Imatinib Mesylate; Days to treatment start: 832 days (2.3 years); Days to treatment end: 887 days (2.4 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Bevacizumab; Days to treatment start: 846 days (2.3 years); Days to treatment end: 887 days (2.4 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Bevacizumab; Days to treatment start: 888 days (2.4 years); Days to treatment end: 948 days (2.6 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan Hydrochloride; Days to treatment start: 888 days (2.4 years); Days to treatment end: 948 days (2.6 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Steroid Therapy; Timepoint category: Preoperative.
   Recorded as not given: Antiseizure Treatment, preoperative; Radiation Therapy, NOS to Head, Face or Neck, NOS, prior to diagnosis.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 26.4 years (9,643 days); Days to diagnosis: 97 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS to Distant Site; Surgery, NOS to Locoregional Site.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 26.6 years (9,710 days); Days to diagnosis: 164 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS to Locoregional Site; Surgery, NOS to Distant Site.
4. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 27.5 years (10,053 days); Days to diagnosis: 507 days (1.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS to Locoregional Site; Surgery, NOS to Distant Site.
5. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 28.4 years (10,378 days); Days to diagnosis: 832 days (2.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS to Locoregional Site; Surgery, NOS to Distant Site.
6. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 28.6 years (10,434 days); Days to diagnosis: 888 days (2.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS to Distant Site; Surgery, NOS to Locoregional Site.
7. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 28.7 years (10,494 days); Days to diagnosis: 948 days (2.6 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS; Surgery, NOS to Locoregional Site; Surgery, NOS to Distant Site.

Follow-up (8 entries)
- Day 6 (prior to adjuvant therapy): Karnofsky performance status: 90.
- Day 97 (post initial treatment): Progression or recurrence: Yes.
- Day 164 (post initial treatment): Progression or recurrence: Yes.
- Day 507 (post initial treatment): Progression or recurrence: Yes.
- Day 832 (post initial treatment): Progression or recurrence: Yes.
- Day 888 (post initial treatment): Progression or recurrence: Yes.
- Day 948 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 987 days (2.7 years); Disease response: With Tumor.

Molecular and laboratory tests
- IDH1 mutation, nos (IHC): Positive.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Headache / Inherited Genetic Syndrome, NOS.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-E1-A7YV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 230 mg.
  Slide TCGA-E1-A7YV-01A-01-TSA: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 90; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-E1-A7YV-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-E1-A7YV-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Oligoastrocytoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; History ionizing radiation to head: No; Tumor status: With tumor; Performance status timing: Pre-Adjuvant Therapy; Tumor site: Supratentorial, Frontal Lobe; Supratentorial localization: Not listed in Medical Record; History seizures: No; History headaches: Yes; Symp changes mental status: No; Symp changes visual: No; Symp changes sensory: No; Symp changes motor movement: No; First symptom longest duration: 0 - 30 Days; History asthma: No; History eczema: No; Histor hay fever: No; History dust mold allergy: No; Allergy food diagnosis indicator: No; Allergy animals insects diagnosis indicator: No; History neoadjuvant steroid treatment: Yes; History neoadjuvant medication: No; Family history brain tumor: No; Idh1 mutation test indicator: Yes; Idh1 mutation found: Yes; Inherited genetic syndrome indicator: Yes; Inherited genetic syndrome specified: 3 X chromosomes (super female) Osler-Weber-Rendu syndrome; Days from index date to performance status: 6; New tumor event diagnosis indicator: Yes.
- New tumor event, Locoregional procedure: New tumor event surgery: No.
- New tumor event, Metastatic procedure: New tumor event surgery met: No.
- New tumor event: New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Drug treatment 1: Pharmaceutical therapy drug name: Temodar; Treatment best response: Clinical Progressive Disease.
- Drug treatment 3: Pharmaceutical therapy drug name: Avastin; Treatment best response: Clinical Progressive Disease.
- Drug treatment 5: Pharmaceutical therapy drug name: Gleevec.
- Drug treatment 6: Pharmaceutical therapy drug name: Gleevec; Treatment best response: Clinical Progressive Disease.
- Drug treatment 10: Pharmaceutical therapy drug name: CPT-11; Treatment best response: Clinical Progressive Disease.
- Radiation treatment: Treatment best response: Radiographic Progressive Disease.
- Follow-up form 1: Lost to follow-up: No; New tumor event diagnosis indicator: Yes; New tumor event surgery: No; Tumor status: With tumor; New tumor event pharmaceutical treatment: Yes; New tumor event radiation treatment: No; New tumor event surgery met: No.
- Follow-up form 5: Lost to follow-up: No; New tumor event diagnosis indicator: Yes; New tumor event surgery: No; Tumor status: With tumor; New tumor event pharmaceutical treatment: No; New tumor event radiation treatment: No; New tumor event surgery met: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 987 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 987 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 97 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-E1-A7YV-01A-11D-A34I-01): tumor purity 0.71, ploidy 3.78, whole-genome doublings 1.
